Somatic mutation profile of tumor specimen MMRF_2459_1_BM_CD138pos (aliquot MMRF_2459_1_BM_CD138pos_T1_KHS5U_L11083) from MMRF case MMRF_2459, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.8 years (24,408 days).
Specimen MMRF_2459_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3870b78b-046c-42a3-92b0-cd60d4505e2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2459_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2459_1_PB_Whole_C3_KHS5U_L11084; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fd2fb26-c25c-4d3f-b644-2c503223176b

The open-access MAF lists 77 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Intron 14, Silent 14, 3'UTR 14, 5'UTR 3, Frame Shift Del 3, Splice Site 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS7 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs200778107; called by muse, mutect2, varscan2
- CCDC114 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749435831, COSV100197138; called by muse, mutect2, varscan2
- DELE1 | c.1535T>C p.L512P | Missense Mutation (SNP) | VAF 114/253 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs920639372; called by muse, mutect2, varscan2
- H3C10 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV60797298, COSV60799019; called by muse, mutect2, varscan2
- HOXA9 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs781712176, COSV58655732; called by muse, mutect2, varscan2
- IGHV2-70 | c.234A>C p.K78N | Missense Mutation (SNP) | VAF 54/85 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs376708751; called by muse, mutect2, varscan2
- LRFN1 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370561531; called by muse, mutect2, varscan2
- PDCD2L | c.592T>C p.Y198H | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs767585398; called by muse, mutect2, varscan2
- ZFPM2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs373471482; called by muse, mutect2, varscan2
- ABI3BP | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP8A2 | c.582-2A>G p.X194_splice | Splice Site (SNP) | VAF 59/122 reads (48%) | called by muse, mutect2, varscan2
- BBS2 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- CACNA1A | c.4214A>G p.K1405R | Missense Mutation (SNP) | VAF 111/235 reads (47%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CDK8 | c.1037_1038del p.F346Cfs*19 | Frame Shift Del (DEL) | VAF 36/59 reads (61%) | called by pindel, varscan2
- DSG3 | c.2386-1G>A p.X796_splice | Splice Site (SNP) | VAF 49/113 reads (43%) | called by muse, mutect2, varscan2
- E2F1 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- HSD17B12 | c.239T>A p.I80N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HSPA14 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IGLV4-3 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 91/198 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCAN | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NFKB2 | c.1040C>A p.S347Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NSUN6 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PIGK | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PSD2 | c.214A>G p.S72G | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- SCN5A | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SEMA4G | c.63del p.S22Hfs*9 | Frame Shift Del (DEL) | VAF 142/300 reads (47%) | called by mutect2, varscan2
- SKIL | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STOML1 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP31 | c.2308_2318del p.S770Qfs*14 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- CILP | c.1062C>T p.L354= | Silent (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- CPNE4 | c.429C>T p.I143= | Silent (SNP) | VAF 57/130 reads (44%) | called by muse, mutect2, varscan2
- FRMD4B | c.2487C>T p.T829= | Silent (SNP) | VAF 65/133 reads (49%) | catalogued as rs975257020; called by muse, mutect2, varscan2
- FZD2 | c.1161C>T p.I387= | Silent (SNP) | VAF 66/144 reads (46%) | catalogued as rs762262772; called by muse, mutect2, varscan2
- GHR | c.303C>T p.C101= | Silent (SNP) | VAF 119/274 reads (43%) | catalogued as CM050055, COSV100052208, COSV50132600; called by muse, mutect2, varscan2
- HSD17B12 | c.240C>T p.I80= | Silent (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.177T>C p.R59= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as rs1180874362; called by muse, varscan2
- LTBP2 | c.1365G>A p.Q455= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- MDGA2 | c.105C>T p.L35= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- NPEPPS | c.1332C>T p.V444= | Silent (SNP) | VAF 50/185 reads (27%) | called by muse, mutect2, varscan2
- OR2T4 | c.873C>T p.Y291= | Silent (SNP) | VAF 267/413 reads (65%) | called by muse, mutect2, varscan2
- OR5M8 | c.759C>A p.T253= | Silent (SNP) | VAF 85/193 reads (44%) | catalogued as rs777315851; called by muse, mutect2, varscan2
- PTBP1 | c.15C>T p.V5= | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as rs773911519, COSV62459473; called by muse, mutect2
- SIAH2 | c.267T>C p.P89= | Silent (SNP) | VAF 87/220 reads (40%) | catalogued as COSV57261653; called by muse, mutect2, varscan2
- AASS | c.*309G>T | 3'UTR (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- ADAM9 | c.333+64C>A | Intron (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- ASAH2B | chr10:50757174 A>G | 3'Flank (SNP) | VAF 50/166 reads (30%) | called by muse, varscan2
- CDK20 | c.564-108C>G | Intron (SNP) | VAF 19/39 reads (49%) | called by muse, varscan2
- CLASRP | c.99+21C>T | Intron (SNP) | VAF 64/115 reads (56%) | called by muse, mutect2, varscan2
- DCLK3 | c.-317C>A | 5'UTR (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- DLG2 | c.1511-18643G>A | Intron (SNP) | VAF 75/123 reads (61%) | called by muse, mutect2, varscan2
- DYNC1LI1 | c.220+179G>A | Intron (SNP) | VAF 68/141 reads (48%) | called by muse, mutect2, varscan2
- FNBP1 | c.*1886A>G | 3'UTR (SNP) | VAF 98/234 reads (42%) | called by muse, varscan2
- G3BP1 | c.*6095G>A | 3'UTR (SNP) | VAF 51/116 reads (44%) | catalogued as rs1044048158; called by muse, mutect2, varscan2
- GDF7 | c.*1747C>T | 3'UTR (SNP) | VAF 10/74 reads (14%) | called by mutect2, varscan2
- HLCS | c.-392-4346G>T | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- KIAA1549 | c.*3291A>C | 3'UTR (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- LNPEP | c.*8594T>A | 3'UTR (SNP) | VAF 38/77 reads (49%) | called by muse, mutect2, varscan2
- LTB | c.163-155C>T | Intron (SNP) | VAF 117/240 reads (49%) | catalogued as COSV53002321; called by muse, mutect2, varscan2
- MGAT5 | c.*275C>A | 3'UTR (SNP) | VAF 55/129 reads (43%) | called by muse, mutect2, varscan2
- MIR5195 | n.36A>G | RNA (SNP) | VAF 53/102 reads (52%) | catalogued as rs1479660203; called by muse, mutect2, varscan2
- MYB | c.1587+217C>T | Intron (SNP) | VAF 64/165 reads (39%) | called by muse, mutect2, varscan2
- OR1D4 | n.357G>A | RNA (SNP) | VAF 41/89 reads (46%) | catalogued as rs777676942; called by muse, mutect2, varscan2
- RBM10 | c.-133C>T | 5'UTR (SNP) | VAF 11/18 reads (61%) | catalogued as COSV52103059; called by muse, mutect2, varscan2
- RFX3 | c.*6519C>T | 3'UTR (SNP) | VAF 80/202 reads (40%) | catalogued as rs749679725; called by muse, mutect2, varscan2
- RPL7 | c.*1+20G>C | Intron (SNP) | VAF 34/58 reads (59%) | called by muse, mutect2, varscan2
- RPS6KB2 | c.79-57G>A | Intron (SNP) | VAF 138/283 reads (49%) | catalogued as rs769602600; called by muse, mutect2, varscan2
- RUSC1 | c.1357+820A>G | Intron (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2
- SLCO1B3 | c.*44G>A | 3'UTR (SNP) | VAF 97/206 reads (47%) | catalogued as COSV99682264; called by muse, mutect2, varscan2
- SMARCA5 | c.*3016del | 3'UTR (DEL) | VAF 24/67 reads (36%) | called by mutect2, pindel, varscan2
- SPEF2 | c.1524+5406C>T | Intron (SNP) | VAF 20/37 reads (54%) | catalogued as rs1458730052; called by muse, mutect2, varscan2
- SPP1 | c.93+810T>G | Intron (SNP) | VAF 20/30 reads (67%) | called by muse, varscan2
- TM9SF3 | c.*2281T>C | 3'UTR (SNP) | VAF 66/136 reads (49%) | called by muse, mutect2, varscan2
- TPD52L3 | c.-112C>A | 5'UTR (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- WDFY3 | c.*1145C>G | 3'UTR (SNP) | VAF 54/109 reads (50%) | called by muse, mutect2, varscan2
- ZMIZ2 | c.994-47_994-46del | Intron (DEL) | VAF 75/196 reads (38%) | called by mutect2, pindel, varscan2
- ZNF385D | c.*1177G>C | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- ZNF606 | c.*330G>A | 3'UTR (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
